Surgical pathology report (de-identified scan), TCGA case TCGA-CN-5355, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-CN-5355-01A (Primary Tumor).

[page 1 of 5]
Pathology Report

Report Type rt
Date of Event
Sex
Authored by
Hosp/Group
Record Status

PATIENT HISTORY:

CHIEF COMPLAINT/ PRE-OP/ POST-OP DIAGNOSIS: Laryngeal mass.

PROCEDURE: Not answered.

SPECIFIC CLINICAL QUESTION: Not answered.

OUTSIDE TISSUE DIAGNOSIS: Not answered.

PRIOR MALIGNANCY: Not answered.

CHEMORADIATION THERAPY: Not answered.

ORGAN TRANSPLANT: Not answered.

IMMUNOSUPPRESSION: Not answered.

ES: Not answered.

FINAL DIAGNOSIS:

PART 1: LARYNX, LEFT, BIOPSY

SQUAMOUS CELL CARCINOMA BASED ON ORIGINAL FROZEN SECTION AND
PERMANENT
SLIDES.

PART 2: LYMPH NODES, LEFT, LEVEL 2, DISSECTION
FOURTEEN BENIGN LYMPH NODES.

PART 3: LYMPH NODES, LEFT, LEVEL 3, DISSECTION
TWO BENIGN LYMPH NODES.

PART 4: LYMPH NODES, LEFT, LEVEL 4, DISSECTION
FOUR BENIGN LYMPH NODES.

PART 5: LYMPH NODES, RIGHT, DISSECTION
SEVEN BENIGN LYMPH NODES.

PART 6: LEFT PHARYNGEAL MARGIN, BIOPSY
NO TUMOR SEEN.

PART 7: RIGHT PHARYNGEAL MARGIN, BIOPSY
NO TUMOR SEEN.

PART 8: POSTCRICOID MARGIN, BIOPSY
NO TUMOR SEEN.

PART 9: LARYNX AND THYROID, TOTAL LARYNGECTOMY AND LEFT THYROID
LOBECTOMY

A. PREDOMINANTLY LEFT TRANSGLOTTIC SQUAMOUS CELL CARCINOMA,
MODERATELY DIFFERENTIATED WITH INVASION OF THYROID CARTILAGE, 3.7 CM.

B. NO PERINEURAL INVASION IS SEEN.

C. MARGINS OF RESECTION ARE FREE OF TUMOR.

D. FOLLICULAR ADENOMA, 0.3 CM, LEFT LOBE OF THYROID

E. NO PARATHYROID GLANDS ARE SEEN.

F. pT4aN0MX

[page 2 of 5]
My signature is attestation that I have personally reviewed the submitted material(s) and the final diagnosis reflects that evaluation.

GROSS DESCRIPTION:

The specimen is received in nine parts.

Part 1 is received labeled with the patient's name, initials xxx and "left

larynx biopsy." The specimen is composed of tissue fragments with overall dimensions of 0.3 x 0.2 x 0.2 cm and is entirely submitted in cassette 1AFS.

Part 2 is received labeled with the patient's name, initials xxx, MRN, and

"left neck dissection, level 2." It is a 12.0 x 2.5 x 0.5 cm yellow-grey-brown tissue with palpable nodularities. The dimension of the

largest possible lymph node is 2.0 cm and possible lymph nodes are submitted

in cassettes 2A-2E (2C and 2E represent bisected lymph nodes).

Part 3 is labeled with the patient's name, initials xxx, MRN and "left neck

level 3." It is a 4.0 x 2.0 x 0.7 cm soft, fatty tissue. The dimension of the

largest possible lymph node is 2.0 cm and possible lymph nodes are submitted

in cassettes 3A and 3B (3A represents the bisected lymph node).

Part 4 is labeled with the patient's name, initials xxx, MRN and "left neck

level 4." It is a 4.0 x 1.5 x 0.5 cm tissue. Possible lymph nodes are submitted in cassettes 4A and 4B (4B represents the bisected lymph node).

Part 5 is labeled with the patient's name, initials xxx, MRN and "right neck

dissection." It is a 4.0 x 1.5 x 0.5 cm tissue. Possible lymph nodes are

submitted in cassettes 5A and 5B.

Part 6 is labeled with the patient's name, initials xxx, MRN and "left pharyngeal margin." It is a 5.0 x 0.3 x 0.2 cm mucosal tissue and is entirely

submitted in cassette 6AFS.

Part 7 is labeled with the patient's name, initials xxx, MRN and "right

pharyngeal margin." It is a 1.0 x 0.6 x 0.2 cm tissue and is entirely submitted in cassette 7AFS.

Part 8 is labeled with the patient's name, initials xxx, MRN and "post cricoid margin." It is a 1.0 x 0.3 x 0.3 cm tissue and is entirely submitted

sette 8AFS.

is labeled with the patient's name, initials, xxx, MRN and "total

laryngectomy and left thyroid lobectomy". It consists of a 9.0 x 8.0 x 5.5 cm

total laryngectomy specimen with a 4.5 x 3.0 x 1.5 cm, 9 gram left thyroid

[page 3 of 5]
lobectomy. On serial sections is a transglottic located tumor of 3.7 x 2.5 x 1.5 cm located mainly on the left side and extending to the right side as well. It has an irregular surface. It is 2.5 cm from the inferior margin and 4.0 cm from the superior margin. On serial sections of the left thyroid lobe are 0.1 cm tan-white areas with no obvious tumor involvement. A portion of tumor and normal mucosa were banked.

Ink code

Black = all margins

Blue = soft tissue after hyoid bone removal (not a margin)

Red = banked area.

Cassette code

9A base of tongue margin

9B inferior tracheal margin

9C representative sections from left thyroid lobe

9D left lateral margin, including pyriform sinus

9E right lateral margin, including pyriform sinus

9F and 9G sections from superior to inferior from left side

9H and 9I tumor samples from left side in relation to epiglottis

9J and 9K tumor samples from superior to inferior on the right side

9L anterior overlying tumor.

ated by: [REDACTED], M.D.

VE CONSULTATION:

PART 1AFS: LEFT LARYNX BIOPSY (frozen section)

A. MALIGNANT.

B. SQUAMOUS CELL CARCINOMA [REDACTED]

PART 6AFS: LEFT PHARYNGEAL MARGI [REDACTED] tion)

A. BENIGN.

B. NO TUMOR SEEN [REDACTED]

PART 7AFS: RIGHT PHARY [REDACTED] frozen section)

A. BENIGN.

B. NO TUMOR SEEN [REDACTED]

PART 8AFS: POST-CRICO [REDACTED] zen section)

A. BENIGN.

NO TUMOR SEEN [REDACTED]

CK COPIC:

copic examination substantiates the above diagnosis.

The following statement applies to all immunohistochemistry, Insitu Hybridization Assays (ISH & FISH), Molecular Anatomic Pathology, and Immunofluorescent Testing:

The testing was developed and its performance characteristics

dete

the [REDACTED], Department of Pathology, as required by

t

regulations. The testing has not been cleared or approved for the specific use by the U.S. Food and Drug Administration, but the FDA has determined such approval is not necessary for clinical use. Tissue fixation

[page 4 of 5]
ranges from a minimum of 2 to a maximum of 84 hours.
This laboratory certified under the Clinical Laboratory Improvement
Amendments of [REDACTED] ("CLIA") as qualified to perform high-complexity
clinical
testing. Pursuant to the requirements of CLIA, ASR's used in this
laboratory
have been established and verified for accuracy and precision.
Additional
information about this type of test is available upon request.

CASE SYNOPSIS:

SYNOPTIC DATA - LARYNX RESECTIONS
TYPE OF LARYNGECTOMY: Total
TUMOR LATERALITY: Left
ATTACHED STRUCTURES: Base of tongue, Thyroid
TUMOR LOCATION/SEGMENT: Transglottic
TUMOR SIZE: Maximum dimension: 3.7 cm
HISTOLOGIC TYPE OF TUMOR: Squamous cell carcinoma
HISTOLOGIC GRADE: Moderately differentiated
STRUCTURES INVOLVED BY TUMOR: True cord, False cord, Epiglottis,
Thyroid
cartilage
LYMPH NODES: Lymph nodes positive, Right: 0
Total number of right sided lymph nodes examined: 7
Lymph nodes positive, Left: 0
Total number of left sided lymph nodes examined: 20
EXTRACAPSULAR SPREAD OF LYMPH NODE METASTASES
No
INTRA-PERINEURAL INVASION: Absent
VASCULAR INVASION: No
SURGICAL MARGIN INVOLVEMENT: Free (2 mm or more)
T STAGE, PATHOLOGIC: Glottis, pT4a
N STAGE, PATHOLOGIC: pN0
M STAGE, PATHOLOGIC: pMX

HISTO TISSUE SUMMARY/SLIDES REVIEWED:

Part 1: Left
Taken: [REDACTED] Received: [REDACTED]
Stain/c
H&E x 1 AFS
Part 2: n Left Neck Lev
Taken: [REDACTED] Received: [REDACTED]
Stain/c
H&E x 1 A
H&E x 1 B
H&E x 1 C
H&E x 1 D
H&E x 1 E
Part 3: l 3
Taken: [REDACTED] Received: [REDACTED]
Stain/c
H&E x 1 A
H&E x 1 B
Part 4: l 4
Taken: [REDACTED] Received: [REDACTED]
Stain/c
H&E x 1 A

[page 5 of 5]
Taken: [REDACTED] Received: [REDACTED]
Stain/chr [REDACTED]

Taken: [REDACTED] Received: [REDACTED]
Stain/chr [REDACTED]

Taken: [REDACTED] Received: [REDACTED]
Stain/chr [REDACTED]

Taken: [REDACTED] Received: [REDACTED]
Stain/chr [REDACTED]

H&E x 1 B
Part 6: 1 Margin

H&E x 1 B
Part 6: 1 Margin

H&E x 1 B
Part 6: 1 Margin

H&E x 1 B
Part 6: 1 Margin

H&E x 1 B
Part 6: 1 Margin

Part 7: al Margin
Taken: [REDACTED] Received: [REDACTED]

Part 7: al Margin
Taken: [REDACTED] Received: [REDACTED]

Part 7: al Margin
Taken: [REDACTED] Received: [REDACTED]

Part 7: al Margin
Taken: [REDACTED] Received: [REDACTED]

Part 8: argin
Taken: Received:

Part 8: argin
Taken: Received:

Part 8: argin
Taken: Received:

Part 8: argin
Taken: Received:

Part 9:
Taken: [REDACTED] Received: [REDACTED]

Part 9:
Taken: [REDACTED] Received: [REDACTED]

Part 9:
Taken: [REDACTED] Received: [REDACTED]

Part 9:
Taken: [REDACTED] Received: [REDACTED]

H&E x 1 B

H&E x 1 B

H&E x 1 B

H&E x 1 B

H&E x 1 B

H&E x 1 B

H&E x 1 B

H&E x 1 B

H&E x 1 B

H&E x 1 B

H&E x 1 B

H&E x 1 B

5

Source: NCI Genomic Data Commons file 6791409e-1de9-488c-8176-afc15d630d65 (TCGA-CN-5355.82168621-371A-44BB-BA43-C921117E550C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).